Somatic mutation profile of tumor specimen ALCH-B1H8-TTP1-A (aliquot ALCH-B1H8-TTP1-A-1-0-D-A714-36) from ALCHEMIST case ALCH-B1H8, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 79.8 years (29,163 days).
Specimen ALCH-B1H8-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 650ceaf1-1920-4278-b4fd-378f2fa61124.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1H8-NB1-A (Blood Derived Normal), aliquot ALCH-B1H8-NB1-A-1-0-D-A714-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/226040ec-76a7-429f-82d8-1dbc6c21dc0c

The open-access MAF lists 60 somatic variants for this specimen: 43 protein-altering or splice-affecting, 12 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, Silent 12, Intron 2, RNA 2, Nonsense Mutation 1, 3'UTR 1, Splice Site 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 123/702 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.818G>T p.R273L | Missense Mutation (SNP) | VAF 87/676 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADGRL3 | c.2903G>C p.C968S (on ENST00000506720 / NM_001322402.2; = p.C900S on NM_015236.6) | Missense Mutation (SNP) | VAF 63/625 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV72231061; called by muse, mutect2, varscan2
- CASP5 | c.1096C>A p.H366N | Missense Mutation (SNP) | VAF 14/171 reads (8%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.758); catalogued as COSV52832361, COSV99508074; called by muse, mutect2
- CCKBR | c.157G>C p.E53Q | Missense Mutation (SNP) | VAF 11/130 reads (8%) | SIFT tolerated (0.5); PolyPhen benign (0.05); catalogued as COSV58102877; called by muse, mutect2
- FTO | c.114C>A p.F38L | Missense Mutation (SNP) | VAF 34/594 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV101150827; called by muse, mutect2
- KLK2 | c.608C>A p.T203K | Missense Mutation (SNP) | VAF 36/329 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV57569736; called by muse, mutect2, varscan2
- PTPRD | c.4910C>T p.T1637M | Missense Mutation (SNP) | VAF 13/180 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.416); catalogued as rs41281783, COSV61953635; called by muse, mutect2
- SLC6A17 | c.1349C>A p.T450K | Missense Mutation (SNP) | VAF 24/297 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV58995468; called by muse, mutect2
- SLIT2 | c.2932G>T p.E978* | Nonsense Mutation (SNP) | VAF 30/362 reads (8%) | catalogued as COSV56563577; called by muse, mutect2
- TAF1 | c.4930G>T p.V1644L (on ENST00000373790 / NM_138923.4; = p.V1665L on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/592 reads (4%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0.006); catalogued as COSV52119553; called by muse, mutect2
- TAPBP | c.451C>T p.L151F | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.018); catalogued as COSV69667272; called by muse, mutect2
- TRPV1 | c.1850G>T p.R617L | Missense Mutation (SNP) | VAF 21/166 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV51519273, COSV99439823; called by muse, mutect2, varscan2
- A4GNT | c.288G>T p.M96I | Missense Mutation (SNP) | VAF 19/658 reads (3%) | SIFT tolerated (0.36); PolyPhen benign (0.001); called by muse, mutect2
- ADGRL4 | c.831C>A p.D277E | Missense Mutation (SNP) | VAF 16/150 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.428); called by muse, mutect2, varscan2
- AKAP6 | c.3148-1G>T p.X1050_splice | Splice Site (SNP) | VAF 16/183 reads (9%) | called by muse, mutect2
- AMIGO3 | c.529C>G p.L177V | Missense Mutation (SNP) | VAF 17/212 reads (8%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.642); called by muse, mutect2
- CDYL2 | c.978G>T p.K326N | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.758); called by muse, mutect2
- CEP68 | c.1640G>C p.G547A | Missense Mutation (SNP) | VAF 18/316 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.104); called by muse, mutect2
- CHM | c.1741G>T p.G581C | Missense Mutation (SNP) | VAF 23/364 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.007); called by muse, mutect2
- DLEU7 | c.605A>G p.D202G | Missense Mutation (SNP) | VAF 44/532 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); called by muse, mutect2
- DSG3 | c.2648C>G p.S883C | Missense Mutation (SNP) | VAF 34/424 reads (8%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.838); called by muse, mutect2
- EPHB6 | c.1321C>G p.L441V | Missense Mutation (SNP) | VAF 27/448 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- KRT33A | c.516C>G p.C172W | Missense Mutation (SNP) | VAF 36/340 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- LRRIQ1 | c.3313G>T p.A1105S | Missense Mutation (SNP) | VAF 21/275 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.063); called by muse, mutect2
- MGAM | c.2821G>T p.D941Y | Missense Mutation (SNP) | VAF 25/212 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.71); called by muse, mutect2, varscan2
- MMGT1 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 36/452 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); called by muse, mutect2
- MROH2A | c.4408G>C p.D1470H | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.033); called by muse, mutect2
- NOTCH4 | c.5191G>T p.D1731Y | Missense Mutation (SNP) | VAF 37/164 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PARVB | c.77G>T p.G26V | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.295); called by muse, mutect2
- PCDHB2 | c.652G>A p.D218N | Missense Mutation (SNP) | VAF 19/281 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2
- RCE1 | c.344C>G p.A115G | Missense Mutation (SNP) | VAF 16/345 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- RYR2 | c.4537G>T p.A1513S | Missense Mutation (SNP) | VAF 33/415 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.179); called by muse, mutect2
- SELENOI | c.1100A>T p.K367M | Missense Mutation (SNP) | VAF 30/294 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.254); called by muse, mutect2
- SEMA6D | c.2382G>T p.K794N (on ENST00000316364 / NM_153618.2; = p.K732N on NM_020858.2) | Missense Mutation (SNP) | VAF 24/360 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0.334); called by muse, mutect2
- SLC39A12 | c.1979G>T p.R660L (on ENST00000377369 / NM_001145195.2; = p.R623L on NM_152725.3) | Missense Mutation (SNP) | VAF 26/438 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.654); called by muse, mutect2
- SLIT2 | c.2933A>T p.E978V | Missense Mutation (SNP) | VAF 28/350 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.143); called by muse, mutect2
- SRSF6 | c.475A>G p.M159V | Missense Mutation (SNP) | VAF 60/844 reads (7%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.93); called by muse, mutect2
- TENT5D | c.569A>C p.K190T | Missense Mutation (SNP) | VAF 36/306 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TRIM61 | c.590G>T p.R197L | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0.25); called by muse, mutect2, varscan2
- ZNF548 | c.824A>T p.H275L | Missense Mutation (SNP) | VAF 11/188 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2
- ZNF713 | c.743G>T p.S248I (on ENST00000633730 / NM_001366796.2; = p.S261I on NM_182633.3) | Missense Mutation (SNP) | VAF 53/359 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- ZNF99 | c.767C>A p.P256H | Missense Mutation (SNP) | VAF 14/174 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.006); called by muse, mutect2
- CCDC168 | c.20661G>A p.A6887= | Silent (SNP) | VAF 22/181 reads (12%) | catalogued as rs867042226, COSV59419961; called by muse, mutect2, varscan2
- CNOT6L | c.423T>A p.I141= (on ENST00000504123 / NM_001286790.2; = p.I136= on NM_144571.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 20/362 reads (6%) | called by muse, mutect2
- CREBBP | c.4323G>T p.R1441= | Silent (SNP) | VAF 69/656 reads (11%) | called by muse, mutect2, varscan2
- DSEL | c.1989A>G p.Q663= | Silent (SNP) | VAF 13/347 reads (4%) | called by muse, mutect2
- GGCX | c.1239C>T p.I413= | Silent (SNP) | VAF 39/762 reads (5%) | called by muse, mutect2
- HSPA2 | c.1233T>A p.G411= | Silent (SNP) | VAF 35/204 reads (17%) | called by muse, mutect2, varscan2
- IGKV1-17 | c.99G>C p.L33= | Silent (SNP) | VAF 60/562 reads (11%) | called by muse, varscan2
- MGA | c.8211G>A p.Q2737= (on ENST00000219905 / NM_001164273.1; = p.Q2528= on NM_001080541.2) | Silent (SNP) | VAF 20/477 reads (4%) | catalogued as COSV54949380; called by muse, mutect2
- PCDHA1 | c.1776G>T p.A592= | Silent (SNP) | VAF 18/324 reads (6%) | catalogued as rs782655473; called by muse, mutect2
- PSD4 | c.792G>A p.E264= | Silent (SNP) | VAF 12/226 reads (5%) | catalogued as rs1558887549; called by muse, mutect2
- STARD3 | c.486C>T p.A162= | Silent (SNP) | VAF 8/180 reads (4%) | called by muse, mutect2
- TNXB | c.8139G>T p.V2713= (on ENST00000647633; = p.V2466= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 27/167 reads (16%) | catalogued as rs1464332746; called by muse, mutect2, varscan2
- CEP170P1 | n.2027T>C | RNA (SNP) | VAF 57/439 reads (13%) | called by muse, mutect2, varscan2
- LYZL2 | c.*14C>T | 3'UTR (SNP) | VAF 32/457 reads (7%) | called by muse, mutect2
- NVL | c.961-1036G>T | Intron (SNP) | VAF 11/118 reads (9%) | called by muse, mutect2
- RCC1 | c.662-236T>A | Intron (SNP) | VAF 11/225 reads (5%) | called by muse, mutect2
- SNORD115-9 | n.23A>T | RNA (SNP) | VAF 25/517 reads (5%) | called by muse, mutect2
